Somatic mutation profile of tumor specimen ALCH-B26Z-TTP1-A (aliquot ALCH-B26Z-TTP1-A-1-0-D-A76N-36) from ALCHEMIST case ALCH-B26Z, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 73.3 years (26,787 days).
Specimen ALCH-B26Z-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b0d00e4d-1804-404f-a6f6-358f6c312d71.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B26Z-NB1-A (Blood Derived Normal), aliquot ALCH-B26Z-NB1-A-1-0-D-A76N-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b40419b1-7eb3-4b0d-baf3-65360c3c7a6b

The open-access MAF lists 306 somatic variants for this specimen: 199 protein-altering or splice-affecting, 73 silent, 34 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 161, Silent 73, Nonsense Mutation 19, Intron 15, Splice Site 10, 3'UTR 8, Frame Shift Del 5, 5'Flank 5, RNA 3, Splice Region 2, 3'Flank 2, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- B2M | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 87/644 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.03); catalogued as rs1057519879, COSV62563048, COSV62563174, COSV62563707; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- MERTK | c.2164C>T p.R722* | Nonsense Mutation (SNP) | VAF 127/1002 reads (13%) | catalogued as rs541717028, CM044665, COSV54923983; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- MET | c.3028G>C p.D1010H | Missense Mutation (SNP) | VAF 289/673 reads (43%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as COSV59259218, COSV59259530, COSV59268643; called by muse, mutect2, varscan2
- TTN | c.47550G>A p.W15850* (on ENST00000591111; = p.W8426* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 17/119 reads (14%) | catalogued as rs794729271; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA10 | c.1880G>A p.R627K | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV52221623; called by muse, mutect2, varscan2
- ABCA12 | c.633C>A p.C211* | Nonsense Mutation (SNP) | VAF 39/276 reads (14%) | catalogued as COSV55959717; called by muse, mutect2, varscan2
- ABCB6 | c.2500G>A p.D834N | Missense Mutation (SNP) | VAF 54/416 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs756521360; called by muse, mutect2, varscan2
- ADGRB3 | c.1420G>C p.G474R | Missense Mutation (SNP) | VAF 65/490 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65402332; called by muse, mutect2, varscan2
- AGAP2 | c.1804G>A p.G602R (on ENST00000547588 / NM_001122772.2; = p.G266R on NM_014770.4) | Missense Mutation (SNP) | VAF 39/304 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as rs771629262, COSV57727884, COSV57731942, COSV99223201; called by muse, mutect2, varscan2
- ANKRD30B | c.2072G>T p.R691M | Missense Mutation (SNP) | VAF 24/117 reads (21%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as rs770905643; called by muse, mutect2, varscan2
- ARHGEF4 | c.2065C>A p.R689S | Missense Mutation (SNP) | VAF 27/183 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.545); catalogued as COSV100388796; called by muse, mutect2, varscan2
- BAZ2B | c.4738A>G p.T1580A | Missense Mutation (SNP) | VAF 70/502 reads (14%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as rs759817790; called by muse, mutect2, varscan2
- C6 | c.2609G>A p.W870* | Nonsense Mutation (SNP) | VAF 92/926 reads (10%) | catalogued as COSV99666679; called by muse, mutect2, varscan2
- CDC20 | c.809G>C p.R270P | Missense Mutation (SNP) | VAF 80/812 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60523365; called by muse, mutect2
- CDH4 | c.1996C>T p.R666C | Missense Mutation (SNP) | VAF 22/193 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs751203963, COSV100848698, COSV64671570; called by muse, mutect2
- CDH4 | c.2581C>A p.P861T | Missense Mutation (SNP) | VAF 31/225 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100849205; called by muse, mutect2, varscan2
- CES1 | c.418C>A p.H140N | Missense Mutation (SNP) | VAF 157/1373 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV62085118; called by muse, mutect2, varscan2
- CLASP1 | c.2150G>A p.R717Q | Missense Mutation (SNP) | VAF 43/393 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.347); catalogued as rs558478108; called by muse, mutect2, varscan2
- COL11A1 | c.3816+1G>T p.X1272_splice | Splice Site (SNP) | VAF 56/560 reads (10%) | catalogued as CD993251, CS982120, CS993225, COSV62175089; called by muse, mutect2
- COL18A1 | c.5107G>A p.E1703K (on ENST00000359759 / NM_130444.3; = p.E1468K on NM_030582.4) | Missense Mutation (SNP) | VAF 63/516 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.086); catalogued as rs370953127; called by muse, mutect2, varscan2
- COL6A1 | c.2914G>T p.V972L | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1223179643; called by muse, mutect2
- CPZ | c.1211C>A p.P404H (on ENST00000360986 / NM_001014447.3; = p.P393H on NM_003652.3) | Missense Mutation (SNP) | VAF 22/156 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as rs1174171647, COSV100249221; called by muse, mutect2, varscan2
- CSMD1 | c.7784del p.L2595* (on ENST00000520002; = p.L2594* on NM_033225.6) | Frame Shift Del (DEL) | VAF 32/284 reads (11%) | catalogued as COSV59374391; called by pindel, varscan2
- CSMD3 | c.1978G>C p.E660Q (on ENST00000297405 / NM_001363185.1; = p.E556Q on NM_052900.3) | Missense Mutation (SNP) | VAF 46/368 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.024); catalogued as COSV52325863, COSV99831993; called by muse, mutect2, varscan2
- CXCL3 | c.224+1G>T p.X75_splice | Splice Site (SNP) | VAF 21/193 reads (11%) | catalogued as rs1458759377; called by muse, mutect2, varscan2
- DDX3X | c.840G>C p.Q280H (on ENST00000399959; = p.Q281H on NM_001356.5) | Missense Mutation (SNP) | VAF 16/418 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67863407, COSV67864668; called by muse, mutect2
- DHX36 | c.2931T>G p.C977W | Missense Mutation (SNP) | VAF 50/441 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.765); catalogued as COSV57672394; called by muse, mutect2, varscan2
- DNAH17 | c.9698C>T p.S3233F | Missense Mutation (SNP) | VAF 58/556 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs749013998; called by muse, mutect2, varscan2
- DRAM1 | c.464C>T p.S155L | Missense Mutation (SNP) | VAF 47/355 reads (13%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as rs557287563; called by muse, mutect2, varscan2
- DSCAML1 | c.1760G>T p.R587M (on ENST00000321322; = p.R527M on NM_020693.4) | Missense Mutation (SNP) | VAF 122/472 reads (26%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV100356575; called by muse, varscan2
- DTNA | c.1768C>A p.P590T | Missense Mutation (SNP) | VAF 63/473 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.588); catalogued as rs75615735; called by muse, mutect2, varscan2
- EBF4 | c.1656G>C p.Q552H (on ENST00000609451; = p.Q548H on NM_001110514.1) | Missense Mutation (SNP) | VAF 44/321 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.95); catalogued as rs1187958761; called by muse, mutect2, varscan2
- EIF5A | c.427G>C p.E143Q | Missense Mutation (SNP) | VAF 52/523 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.123); catalogued as COSV59748064; called by muse, mutect2, varscan2
- H2AC4 | c.364G>A p.E122K | Missense Mutation (SNP) | VAF 56/483 reads (12%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as rs745693623, COSV52518212, COSV52518824; called by muse, mutect2
- HUWE1 | c.676A>G p.I226V | Missense Mutation (SNP) | VAF 30/341 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.017); catalogued as rs1241433259, COSV53335897; called by muse, mutect2
- ITGB3 | c.1156C>A p.R386S | Missense Mutation (SNP) | VAF 79/763 reads (10%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.742); catalogued as COSV71383470; called by muse, mutect2, varscan2
- KCNH5 | c.1618C>G p.L540V | Missense Mutation (SNP) | VAF 53/426 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.899); catalogued as COSV59762476; called by muse, mutect2, varscan2
- KDM6A | c.1661C>G p.S554C | Missense Mutation (SNP) | VAF 106/951 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.469); catalogued as COSV65040033; called by muse, mutect2, varscan2
- KIF2B | c.595G>T p.D199Y | Missense Mutation (SNP) | VAF 67/538 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); catalogued as COSV52132538, COSV52134270; called by muse, mutect2, varscan2
- KLK10 | c.94G>C p.E32Q | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0.017); catalogued as rs911685192, COSV100010979; called by muse, mutect2, varscan2
- KRTAP4-7 | c.233G>C p.R78T | Missense Mutation (SNP) | VAF 88/634 reads (14%) | SIFT tolerated (0.38); PolyPhen benign (0.005); catalogued as rs776071282; called by muse, mutect2, varscan2
- KRTAP5-7 | c.35C>T p.S12F | Missense Mutation (SNP) | VAF 82/435 reads (19%) | PolyPhen probably damaging (0.955); catalogued as rs1255787712; called by muse, mutect2, varscan2
- LILRA2 | c.985C>A p.Q329K | Missense Mutation (SNP) | VAF 159/795 reads (20%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.451); catalogued as COSV52192924; called by muse, mutect2, varscan2
- LRRC74B | c.1039G>T p.A347S | Missense Mutation (SNP) | VAF 21/190 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs1198611813, COSV100699895; called by muse, mutect2, varscan2
- LRRC9 | c.1199G>A p.R400Q | Missense Mutation (SNP) | VAF 18/135 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs1456713040, COSV54296100; called by muse, mutect2, varscan2
- MORN1 | c.116A>G p.Y39C | Missense Mutation (SNP) | VAF 61/481 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1312700916; called by muse, mutect2, varscan2
- MUC16 | c.24781G>T p.E8261* | Nonsense Mutation (SNP) | VAF 43/204 reads (21%) | catalogued as COSV101197482, COSV67473804; called by muse, mutect2, varscan2
- MUC4 | c.1444C>G p.L482V | Missense Mutation (SNP) | VAF 65/501 reads (13%) | SIFT tolerated, low confidence (0.86); PolyPhen benign (0.374); catalogued as rs763408302; called by muse, mutect2, varscan2
- NAV3 | c.2261G>T p.G754V | Missense Mutation (SNP) | VAF 53/472 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57102624; called by muse, mutect2, varscan2
- NCSTN | c.1393G>A p.V465M | Missense Mutation (SNP) | VAF 81/797 reads (10%) | SIFT tolerated (0.44); PolyPhen benign (0.046); catalogued as rs200757075; called by muse, mutect2, varscan2
- NLRP3 | c.2767G>T p.G923* | Nonsense Mutation (SNP) | VAF 65/551 reads (12%) | catalogued as COSV60220242, COSV60225995; called by muse, mutect2, varscan2
- OR51B5 | c.418G>T p.V140L | Missense Mutation (SNP) | VAF 14/105 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.006); catalogued as COSV56175486; called by muse, varscan2
- OSGEP | c.479G>T p.C160F | Missense Mutation (SNP) | VAF 58/512 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs750199393; called by muse, mutect2, varscan2
- PCDH11X | c.2668G>A p.E890K | Missense Mutation (SNP) | VAF 70/629 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.19); catalogued as COSV100011438, COSV53492176; called by muse, mutect2, varscan2
- PCDHB3 | c.1079C>T p.S360L | Missense Mutation (SNP) | VAF 11/138 reads (8%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.028); catalogued as rs1419014858, COSV99164074; called by muse, mutect2
- PHOX2A | c.554C>T p.T185M | Missense Mutation (SNP) | VAF 31/315 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as rs1310241620; called by muse, mutect2
- PLEKHA1 | c.1024C>T p.R342* | Nonsense Mutation (SNP) | VAF 82/630 reads (13%) | catalogued as rs200164610, COSV64569669; called by muse, mutect2, varscan2
- PLXNB3 | c.1199T>C p.V400A | Missense Mutation (SNP) | VAF 46/374 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as rs1408216858; called by muse, mutect2, varscan2
- POU2AF1 | c.64G>T p.V22F | Missense Mutation (SNP) | VAF 46/328 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67577201; called by muse, varscan2
- PRR23A | c.125C>T p.A42V | Missense Mutation (SNP) | VAF 17/125 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.445); catalogued as COSV67214743; called by muse, mutect2, varscan2
- PRUNE2 | c.5742G>T p.Q1914H | Missense Mutation (SNP) | VAF 94/370 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.879); catalogued as COSV65046412; called by muse, mutect2, varscan2
- PYHIN1 | c.1375C>G p.P459A | Missense Mutation (SNP) | VAF 72/488 reads (15%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.049); catalogued as COSV63730465; called by muse, mutect2, varscan2
- RALYL | c.64C>A p.R22S | Missense Mutation (SNP) | VAF 72/655 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101568993, COSV72818944; called by muse, mutect2, varscan2
- RBM10 | c.1693+1G>T p.X565_splice | Splice Site (SNP) | VAF 95/776 reads (12%) | catalogued as COSV61307776, COSV61307835, COSV61309060; called by muse, mutect2, varscan2
- RIMS2 | c.613C>G p.R205G | Missense Mutation (SNP) | VAF 55/597 reads (9%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.976); catalogued as COSV68113100; called by muse, mutect2
- RYR2 | c.2374G>C p.V792L | Missense Mutation (SNP) | VAF 45/491 reads (9%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.636); catalogued as COSV63670051; called by muse, mutect2
- SCML4 | c.373G>A p.E125K | Missense Mutation (SNP) | VAF 40/436 reads (9%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.711); catalogued as rs372302614, COSV100940276; called by muse, mutect2
- SCP2D1 | c.331C>A p.P111T | Missense Mutation (SNP) | VAF 53/485 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.474); catalogued as COSV53857431; called by muse, mutect2, varscan2
- SIPA1L1 | c.1592C>T p.S531F | Missense Mutation (SNP) | VAF 34/294 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.037); catalogued as COSV62170344; called by muse, mutect2, varscan2
- SLC26A7 | c.609G>T p.M203I | Missense Mutation (SNP) | VAF 35/277 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as rs755245272; called by muse, mutect2, varscan2
- SPATA31A7 | c.358C>A p.P120T | Missense Mutation (SNP) | VAF 174/1009 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.514); catalogued as rs1326498284; called by muse, mutect2, varscan2
- ST8SIA3 | c.465G>A p.M155I | Missense Mutation (SNP) | VAF 46/313 reads (15%) | PolyPhen benign (0); catalogued as rs746477485, COSV60655270; called by muse, mutect2, varscan2
- TLNRD1 | c.394C>G p.L132V | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.848); catalogued as rs747927954, COSV51256815, COSV51257583; called by muse, mutect2, varscan2
- TRDN | c.456G>C p.E152D | Missense Mutation (SNP) | VAF 5/80 reads (6%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.257); catalogued as COSV100520410; called by muse, mutect2
- TTC26 | c.1081G>T p.G361W | Missense Mutation (SNP) | VAF 116/388 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100571159; called by muse, mutect2, varscan2
- UGT1A8 | c.365C>G p.S122W | Missense Mutation (SNP) | VAF 43/248 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV65078464; called by muse, mutect2, varscan2
- UNC5A | c.302C>A p.T101N | Missense Mutation (SNP) | VAF 14/122 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV56171957; called by muse, mutect2, varscan2
- UTP20 | c.3259A>G p.K1087E | Missense Mutation (SNP) | VAF 42/441 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.055); catalogued as rs1266173274, COSV55384922; called by muse, mutect2
- UXS1 | c.1033G>A p.G345R | Missense Mutation (SNP) | VAF 44/490 reads (9%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs773855011; called by muse, mutect2
- ZNF208 | c.214G>C p.E72Q | Missense Mutation (SNP) | VAF 33/276 reads (12%) | SIFT tolerated (0.54); PolyPhen benign (0.196); catalogued as rs1345152525; called by muse, mutect2, varscan2
- ZNF714 | c.865G>T p.E289* | Nonsense Mutation (SNP) | VAF 32/260 reads (12%) | catalogued as COSV99395527; called by muse, mutect2, varscan2
- ACAD11 | c.973A>G p.S325G | Missense Mutation (SNP) | VAF 25/157 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- ADAM11 | c.1321-1G>T p.X441_splice | Splice Site (SNP) | VAF 26/241 reads (11%) | called by muse, mutect2, varscan2
- ADAM19 | c.2666C>A p.P889H | Missense Mutation (SNP) | VAF 58/520 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.557); called by muse, mutect2, varscan2
- ADAM29 | c.2257C>G p.Q753E | Missense Mutation (SNP) | VAF 96/325 reads (30%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADAM7 | c.1301G>T p.C434F | Missense Mutation (SNP) | VAF 59/482 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AGBL1 | c.969+2T>C p.X323_splice | Splice Site (SNP) | VAF 35/249 reads (14%) | called by muse, mutect2, varscan2
- AGPAT1 | c.315G>T p.Q105H | Missense Mutation (SNP) | VAF 18/109 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- AKAP6 | c.6520G>T p.A2174S | Missense Mutation (SNP) | VAF 78/475 reads (16%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ARCN1 | c.1300C>T p.R434* | Nonsense Mutation (SNP) | VAF 34/914 reads (4%) | called by muse, mutect2
- ARHGAP30 | c.2536G>A p.E846K | Missense Mutation (SNP) | VAF 45/324 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- ARHGEF9 | c.256C>G p.P86A | Missense Mutation (SNP) | VAF 17/210 reads (8%) | SIFT tolerated (0.52); PolyPhen benign (0.003); called by muse, mutect2
- BIRC6 | c.11225C>A p.S3742Y | Missense Mutation (SNP) | VAF 62/578 reads (11%) | SIFT tolerated (0.35); PolyPhen benign (0.056); called by muse, mutect2
- BRD8 | c.391G>C p.A131P | Missense Mutation (SNP) | VAF 55/607 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); called by muse, mutect2
- CACYBP | c.433-23_444del p.X145_splice | Splice Site (DEL) | VAF 20/231 reads (9%) | called by mutect2, pindel
- CKAP5 | c.2839A>G p.I947V | Missense Mutation (SNP) | VAF 58/344 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- CLCN3 | c.1883G>C p.G628A | Missense Mutation (SNP) | VAF 111/460 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- CLSTN3 | c.384G>T p.K128N | Missense Mutation (SNP) | VAF 24/215 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.179); called by muse, mutect2, varscan2
- CNKSR2 | c.1635C>A p.H545Q | Missense Mutation (SNP) | VAF 26/287 reads (9%) | SIFT tolerated (0.52); PolyPhen benign (0.001); called by muse, mutect2
- CNTN5 | c.542G>T p.S181I | Missense Mutation (SNP) | VAF 42/178 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- COL4A1 | c.3057A>T p.P1019= | Splice Region (SNP) | VAF 196/900 reads (22%) | called by muse, mutect2, varscan2
- COL4A5 | c.1717G>T p.G573C | Missense Mutation (SNP) | VAF 66/466 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COPS5 | c.855_856insT p.M286Yfs*8 | Frame Shift Ins (INS) | VAF 62/560 reads (11%) | called by mutect2, pindel*, varscan2
- CTNND2 | c.206T>A p.L69Q | Missense Mutation (SNP) | VAF 92/475 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.524); called by muse, mutect2, varscan2
- DBN1 | c.208G>A p.V70I | Missense Mutation (SNP) | VAF 60/480 reads (13%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.95); called by muse, varscan2
- DCD | c.236G>C p.G79A | Missense Mutation (SNP) | VAF 100/1020 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.702); called by muse, mutect2
- DEPDC5 | c.271G>T p.D91Y | Missense Mutation (SNP) | VAF 39/326 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, varscan2
- DICER1 | c.3544C>G p.Q1182E | Missense Mutation (SNP) | VAF 72/469 reads (15%) | SIFT tolerated, low confidence (0.86); PolyPhen benign (0); called by muse, mutect2, varscan2
- DKK2 | c.131G>T p.G44V | Missense Mutation (SNP) | VAF 137/817 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ENDOV | c.301G>A p.V101M | Missense Mutation (SNP) | VAF 70/566 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- ETAA1 | c.1833C>A p.Y611* | Nonsense Mutation (SNP) | VAF 24/167 reads (14%) | called by muse, mutect2, varscan2
- EYS | c.4631A>T p.Q1544L | Missense Mutation (SNP) | VAF 45/440 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- FADS2 | c.562T>C p.Y188H | Missense Mutation (SNP) | VAF 71/533 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- FAM217A | c.678G>C p.L226F | Missense Mutation (SNP) | VAF 20/145 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- FBN2 | c.2445A>T p.L815F | Missense Mutation (SNP) | VAF 95/820 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.211); called by muse, mutect2, varscan2
- FBXW4 | c.586T>G p.S196A | Missense Mutation (SNP) | VAF 35/260 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.007); called by mutect2, varscan2
- FCN1 | c.293T>C p.M98T | Missense Mutation (SNP) | VAF 52/609 reads (9%) | SIFT tolerated (0.55); PolyPhen benign (0.001); called by muse, mutect2
- FGG | c.86C>A p.A29D | Missense Mutation (SNP) | VAF 81/717 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.312); called by muse, mutect2, varscan2
- FLRT2 | c.985C>A p.P329T | Missense Mutation (SNP) | VAF 46/410 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- FLT4 | c.2647+6G>C | Splice Region (SNP) | VAF 45/195 reads (23%) | called by muse, mutect2, varscan2
- FPR3 | c.292T>C p.C98R | Missense Mutation (SNP) | VAF 56/254 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FRMD6 | c.1735G>A p.E579K (on ENST00000344768 / NM_001267046.2; = p.E571K on NM_152330.4) | Missense Mutation (SNP) | VAF 70/502 reads (14%) | SIFT tolerated (0.46); PolyPhen benign (0); called by muse, mutect2, varscan2
- GPC3 | c.25T>C p.C9R | Missense Mutation (SNP) | VAF 20/238 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.645); called by muse, mutect2
- GPRIN1 | c.571G>A p.G191R | Missense Mutation (SNP) | VAF 30/216 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- HDAC6 | c.1981G>C p.E661Q | Missense Mutation (SNP) | VAF 43/469 reads (9%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.705); called by muse, mutect2
- IARS2 | c.2482G>A p.D828N | Missense Mutation (SNP) | VAF 34/419 reads (8%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.985); called by muse, mutect2
- IGHMBP2 | c.1126G>T p.E376* | Nonsense Mutation (SNP) | VAF 44/492 reads (9%) | called by muse, mutect2
- IGHV1-18 | c.172C>T p.Q58* | Nonsense Mutation (SNP) | VAF 99/1007 reads (10%) | called by muse, mutect2, varscan2
- IGHV1-45 | c.278G>C p.R93T | Missense Mutation (SNP) | VAF 75/816 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- KCNC2 | c.983T>A p.L328* | Nonsense Mutation (SNP) | VAF 69/700 reads (10%) | called by muse, mutect2
- KLHL12 | c.239C>G p.T80S | Missense Mutation (SNP) | VAF 62/574 reads (11%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- LGI3 | c.1341G>C p.K447N | Missense Mutation (SNP) | VAF 54/381 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- LPXN | c.135G>T p.E45D | Missense Mutation (SNP) | VAF 45/321 reads (14%) | SIFT tolerated (0.52); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- LRP12 | c.1409G>T p.C470F | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, varscan2
- LRP12 | c.1388_1392del p.C463Ffs*2 | Frame Shift Del (DEL) | VAF 8/73 reads (11%) | called by pindel, varscan2
- MAGEA1 | c.866G>C p.R289T | Missense Mutation (SNP) | VAF 28/228 reads (12%) | SIFT tolerated (1); PolyPhen possibly damaging (0.541); called by muse, mutect2
- MAPK15 | c.331G>C p.D111H | Missense Mutation (SNP) | VAF 30/217 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MAST4 | c.5408G>T p.G1803V (on ENST00000403625 / NM_001164664.2; = p.G1614V on NM_015183.3) | Missense Mutation (SNP) | VAF 43/386 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MED13 | c.540T>G p.I180M | Missense Mutation (SNP) | VAF 49/470 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- MICALL1 | c.907C>T p.P303S | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2
- MYH4 | c.3761G>T p.R1254L | Missense Mutation (SNP) | VAF 46/349 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); called by muse, mutect2, varscan2
- NAA15 | c.761del p.N254Ifs*21 | Frame Shift Del (DEL) | VAF 142/682 reads (21%) | called by mutect2, pindel, varscan2
- NBEA | c.4750G>C p.E1584Q | Missense Mutation (SNP) | VAF 60/565 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- NEB | c.12855G>C p.E4285D | Missense Mutation (SNP) | VAF 59/542 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- NRXN3 | c.1771G>C p.E591Q (on ENST00000557594 / NM_001272020.2; = p.E1015Q on NM_004796.6) | Missense Mutation (SNP) | VAF 43/385 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- NUF2 | c.556G>C p.G186R | Missense Mutation (SNP) | VAF 34/406 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2
- NUP37 | c.153T>G p.F51L | Missense Mutation (SNP) | VAF 14/114 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.311); called by muse, mutect2
- OR11G2 | c.661C>A p.P221T | Missense Mutation (SNP) | VAF 45/431 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- OR2AJ1 | c.329G>T p.G110V | Missense Mutation (SNP) | VAF 62/386 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); called by muse, mutect2, varscan2
- OR2W1 | c.326C>G p.S109* | Nonsense Mutation (SNP) | VAF 36/246 reads (15%) | called by muse, mutect2, varscan2
- OR4D10 | c.684G>T p.Q228H | Missense Mutation (SNP) | VAF 25/230 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- OR51Q1 | c.593G>A p.S198N | Missense Mutation (SNP) | VAF 32/334 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.023); called by muse, mutect2
- OSBPL8 | c.1353G>T p.E451D | Missense Mutation (SNP) | VAF 23/179 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- PADI6 | c.346G>T p.V116L | Missense Mutation (SNP) | VAF 62/515 reads (12%) | SIFT tolerated (0.75); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- PCDH11X | c.2822C>G p.S941C | Missense Mutation (SNP) | VAF 125/899 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PCNX1 | c.6647G>T p.G2216V | Missense Mutation (SNP) | VAF 47/363 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.763); called by muse, mutect2, varscan2
- PDZD11 | c.420C>A p.H140Q | Missense Mutation (SNP) | VAF 56/546 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.969); called by muse, mutect2
- PHYH | c.13C>T p.R5C | Missense Mutation (SNP) | VAF 75/454 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- PLEKHF1 | c.7G>T p.D3Y | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- PLXNA3 | c.4928G>A p.G1643E | Missense Mutation (SNP) | VAF 43/263 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PNMA8A | c.398C>A p.P133H | Missense Mutation (SNP) | VAF 19/153 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.54); called by muse, mutect2, varscan2
- PPP3CA | c.647A>T p.D216V | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); called by mutect2, varscan2
- PRICKLE3 | c.319C>G p.Q107E | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- RAI1 | c.5566-1G>C p.X1856_splice | Splice Site (SNP) | VAF 69/603 reads (11%) | called by muse, mutect2, varscan2
- RASGEF1C | c.790A>G p.T264A | Missense Mutation (SNP) | VAF 26/278 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2
- RET | c.1274T>G p.V425G | Missense Mutation (SNP) | VAF 62/654 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); called by muse, mutect2
- SAMD9 | c.2877G>C p.K959N | Missense Mutation (SNP) | VAF 157/1313 reads (12%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- SEC22A | c.488G>T p.G163V | Missense Mutation (SNP) | VAF 61/442 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SFTPB | c.988_1002+6del p.X330_splice | Splice Site (DEL) | VAF 74/920 reads (8%) | called by mutect2, pindel
- SLC13A1 | c.1071G>A p.M357I | Missense Mutation (SNP) | VAF 78/781 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SLC25A21 | c.322C>G p.P108A | Missense Mutation (SNP) | VAF 29/287 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- SLC26A3 | c.286C>A p.L96M | Missense Mutation (SNP) | VAF 79/581 reads (14%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC34A1 | c.1686G>C p.Q562H | Missense Mutation (SNP) | VAF 16/146 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); called by muse, mutect2
- SLITRK3 | c.434T>A p.F145Y | Missense Mutation (SNP) | VAF 22/255 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2
- SMG5 | c.283A>G p.K95E | Missense Mutation (SNP) | VAF 35/313 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- TAS2R40 | c.697G>A p.G233R | Missense Mutation (SNP) | VAF 164/551 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TBX4 | c.137del p.S46Tfs*42 | Frame Shift Del (DEL) | VAF 9/78 reads (12%) | called by mutect2, pindel, varscan2
- TENT4B | c.930+1_930+2del p.X310_splice (on ENST00000561678 / NM_001365323.2; = p.X295_splice on NM_001040284.3 and 1 other RefSeq transcript) | Splice Site (DEL) | VAF 74/331 reads (22%) | called by mutect2, pindel, varscan2
- THADA | c.172-13_186del p.X58_splice | Splice Site (DEL) | VAF 26/274 reads (9%) | called by mutect2, pindel
- TLR7 | c.1853G>T p.S618I | Missense Mutation (SNP) | VAF 55/433 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TM6SF2 | c.240C>G p.I80M | Missense Mutation (SNP) | VAF 62/484 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- TMTC1 | c.2597T>A p.L866* (on ENST00000539277 / NM_001193451.2; = p.L758* on NM_175861.3) | Nonsense Mutation (SNP) | VAF 72/668 reads (11%) | called by muse, mutect2, varscan2
- TRAJ21 | c.26G>T p.G9V | Missense Mutation (SNP) | VAF 35/329 reads (11%) | called by muse, mutect2, varscan2
- TRIM21 | c.243G>T p.Q81H | Missense Mutation (SNP) | VAF 77/449 reads (17%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.72); called by muse, mutect2, varscan2
- TRPC5 | c.2772C>G p.S924R | Missense Mutation (SNP) | VAF 23/143 reads (16%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- TRPC6 | c.155G>T p.G52V | Missense Mutation (SNP) | VAF 24/243 reads (10%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- TTN | c.38064G>C p.E12688D (on ENST00000591111; = p.E5264D on NM_003319.4) | Missense Mutation (SNP) | VAF 19/155 reads (12%) | PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- TXNIP | c.287_290del p.K96Mfs*25 | Frame Shift Del (DEL) | VAF 41/286 reads (14%) | called by mutect2, pindel, varscan2
- UBR1 | c.206C>G p.S69* | Nonsense Mutation (SNP) | VAF 56/395 reads (14%) | called by muse, mutect2, varscan2
- UPRT | c.595T>A p.C199S | Missense Mutation (SNP) | VAF 32/264 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- USH2A | c.11138C>A p.S3713Y | Missense Mutation (SNP) | VAF 62/511 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- USP18 | c.385A>T p.K129* | Nonsense Mutation (SNP) | VAF 31/247 reads (13%) | called by muse, mutect2, varscan2
- VNN1 | c.473A>G p.Y158C | Missense Mutation (SNP) | VAF 62/445 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- WDR93 | c.1837G>C p.E613Q | Missense Mutation (SNP) | VAF 34/268 reads (13%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- XIRP2 | c.205G>C p.E69Q | Missense Mutation (SNP) | VAF 41/302 reads (14%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); called by muse, varscan2
- ZC3H11A | c.831A>T p.R277S | Missense Mutation (SNP) | VAF 28/252 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.234); called by muse, mutect2, varscan2
- ZMAT4 | c.594C>A p.Y198* | Nonsense Mutation (SNP) | VAF 32/358 reads (9%) | called by muse, mutect2
- ZNF517 | c.75G>C p.R25S | Missense Mutation (SNP) | VAF 56/512 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.235); called by muse, mutect2
- ZNRF4 | c.94C>T p.Q32* | Nonsense Mutation (SNP) | VAF 63/363 reads (17%) | called by muse, mutect2, varscan2
- ADAMTS12 | c.1158G>C p.L386= | Silent (SNP) | VAF 36/302 reads (12%) | called by muse, mutect2, varscan2
- ADAMTSL2 | c.2190G>A p.K730= | Silent (SNP) | VAF 82/868 reads (9%) | called by muse, mutect2
- ADRA2A | c.258C>T p.F86= | Silent (SNP) | VAF 48/400 reads (12%) | catalogued as rs375858769; called by muse, mutect2, varscan2
- ANKRD34A | c.690G>T p.P230= | Silent (SNP) | VAF 12/118 reads (10%) | catalogued as rs587718650; called by muse, mutect2
- ARHGEF19 | c.987G>T p.G329= | Silent (SNP) | VAF 17/93 reads (18%) | called by muse, mutect2, varscan2
- BEGAIN | c.801C>T p.A267= | Silent (SNP) | VAF 26/172 reads (15%) | catalogued as rs377304767; called by muse, varscan2
- BMP2K | c.1827C>T p.F609= | Silent (SNP) | VAF 69/759 reads (9%) | catalogued as rs1416071002; called by muse, mutect2
- BTNL8 | c.537C>A p.S179= | Silent (SNP) | VAF 190/841 reads (23%) | catalogued as COSV99180521; called by muse, mutect2, varscan2
- BVES | c.480T>G p.T160= | Silent (SNP) | VAF 142/582 reads (24%) | catalogued as COSV58947014; called by muse, varscan2
- CACNA1F | c.4143T>C p.T1381= | Silent (SNP) | VAF 27/301 reads (9%) | called by muse, mutect2
- CACNA1F | c.105G>A p.V35= | Silent (SNP) | VAF 32/356 reads (9%) | called by muse, mutect2
- CACNB2 | c.1467C>A p.P489= (on ENST00000324631 / NM_201596.3; = p.P434= on NM_000724.4) | Silent (SNP) | VAF 30/255 reads (12%) | called by muse, mutect2, varscan2
- CAMSAP3 | c.225A>G p.T75= | Silent (SNP) | VAF 39/251 reads (16%) | catalogued as rs1256623361; called by muse, mutect2, varscan2
- CEP170 | c.156G>T p.T52= | Silent (SNP) | VAF 53/505 reads (10%) | catalogued as COSV100839765; called by muse, mutect2, varscan2
- COL4A5 | c.2193A>T p.G731= | Silent (SNP) | VAF 40/472 reads (8%) | called by muse, mutect2
- COL6A3 | c.3774G>T p.L1258= | Silent (SNP) | VAF 47/446 reads (11%) | catalogued as rs770715258; called by muse, mutect2, varscan2
- CTSA | c.1245C>G p.L415= | Silent (SNP) | VAF 43/352 reads (12%) | called by muse, mutect2, varscan2
- DCDC1 | c.4809T>C p.P1603= (on ENST00000597505 / NM_001367979.1; = p.P710= on NM_020869.3) | Silent (SNP) | VAF 39/336 reads (12%) | called by muse, varscan2
- DDHD2 | c.1920A>T p.A640= | Silent (SNP) | VAF 26/282 reads (9%) | called by muse, mutect2
- DDOST | c.456G>A p.E152= (on ENST00000415136; = p.E135= on NM_005216.5) | Silent (SNP) | VAF 44/514 reads (9%) | called by muse, mutect2
- DUSP6 | c.348G>A p.G116= | Silent (SNP) | VAF 21/160 reads (13%) | catalogued as COSV54378679; called by muse, mutect2, varscan2
- EXT2 | c.360C>T p.V120= (on ENST00000343631; = p.V153= on NM_000401.3) | Silent (SNP) | VAF 78/603 reads (13%) | called by muse, mutect2, varscan2
- GADD45B | c.231C>T p.L77= | Silent (SNP) | VAF 32/322 reads (10%) | catalogued as COSV99297959; called by muse, mutect2
- GPR50 | c.177C>A p.L59= | Silent (SNP) | VAF 25/143 reads (17%) | catalogued as COSV54437847; called by muse, mutect2, varscan2
- H2AC4 | c.366G>A p.E122= | Silent (SNP) | VAF 58/486 reads (12%) | catalogued as COSV99451596; called by muse, mutect2
- HCRT | c.219C>A p.P73= | Silent (SNP) | VAF 25/155 reads (16%) | called by muse, mutect2, varscan2
- HNF4A | c.153C>A p.P51= | Silent (SNP) | VAF 78/567 reads (14%) | called by muse, mutect2, varscan2
- HNRNPCL1 | c.576G>A p.Q192= | Silent (SNP) | VAF 77/614 reads (13%) | catalogued as rs1320075698, COSV58616107; called by muse, mutect2, varscan2
- IGHMBP2 | c.1125C>T p.D375= | Silent (SNP) | VAF 46/500 reads (9%) | catalogued as rs140296831; ClinVar: likely benign / uncertain significance; called by muse, mutect2
- INPP5D | c.2202C>T p.L734= (on ENST00000445964 / NM_001017915.3; = p.L733= on NM_005541.5) | Silent (SNP) | VAF 55/484 reads (11%) | called by muse, mutect2, varscan2
- ITGA8 | c.1344C>T p.S448= | Silent (SNP) | VAF 52/342 reads (15%) | catalogued as rs779402009; called by muse, mutect2, varscan2
- JMY | c.2602C>T p.L868= | Silent (SNP) | VAF 10/107 reads (9%) | called by muse, mutect2
- KCNMA1 | c.3504G>A p.P1168= (on ENST00000286628 / NM_001161352.2; = p.P1110= on NM_002247.4) | Silent (SNP) | VAF 56/428 reads (13%) | catalogued as rs200945011, COSV54260206; called by muse, mutect2, varscan2
- LRFN4 | c.231G>C p.L77= | Silent (SNP) | VAF 60/444 reads (14%) | called by muse, mutect2, varscan2
- LRRTM4 | c.846G>A p.L282= | Silent (SNP) | VAF 13/150 reads (9%) | catalogued as COSV69139392, COSV69140820; called by muse, mutect2
- MECOM | c.2142C>T p.F714= (on ENST00000468789 / NM_001105078.4; = p.F902= on NM_004991.4) | Silent (SNP) | VAF 53/475 reads (11%) | called by muse, varscan2
- MMRN2 | c.1734G>A p.L578= | Silent (SNP) | VAF 28/207 reads (14%) | called by muse, mutect2, varscan2
- MTX2 | c.84G>A p.L28= | Silent (SNP) | VAF 53/419 reads (13%) | called by muse, mutect2, varscan2
- MUC5AC | c.1083C>A p.S361= | Silent (SNP) | VAF 18/207 reads (9%) | called by muse, mutect2
- MYH13 | c.5208T>A p.A1736= | Silent (SNP) | VAF 81/589 reads (14%) | called by muse, mutect2, varscan2
- MYOCD | c.1101C>A p.L367= | Silent (SNP) | VAF 46/382 reads (12%) | called by muse, mutect2, varscan2
- NKX2-4 | c.84C>T p.S28= | Silent (SNP) | VAF 15/99 reads (15%) | called by muse, mutect2, varscan2
- OR1C1 | c.735G>T p.L245= | Silent (SNP) | VAF 28/171 reads (16%) | catalogued as COSV101376299; called by muse, mutect2, varscan2
- OR2L5 | c.759C>A p.P253= | Silent (SNP) | VAF 38/286 reads (13%) | called by muse, varscan2
- OR4C6 | c.444G>T p.V148= | Silent (SNP) | VAF 25/266 reads (9%) | catalogued as COSV58602819; called by muse, mutect2
- OSBPL2 | c.651C>T p.G217= (on ENST00000313733 / NM_144498.4; = p.G205= on NM_014835.4) | Silent (SNP) | VAF 32/224 reads (14%) | called by muse, mutect2, varscan2
- OTOGL | c.1302T>C p.N434= (on ENST00000547103; = p.N425= on NM_173591.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 32/308 reads (10%) | called by muse, mutect2, varscan2
- PCDH10 | c.1659G>C p.A553= | Silent (SNP) | VAF 109/697 reads (16%) | called by muse, mutect2, varscan2
- PCSK6 | c.954C>A p.P318= | Silent (SNP) | VAF 31/198 reads (16%) | called by muse, mutect2, varscan2
- PITPNB | c.324C>T p.F108= | Silent (SNP) | VAF 37/298 reads (12%) | catalogued as COSV100087098; called by muse, mutect2, varscan2
- POR | c.1464C>T p.I488= | Silent (SNP) | VAF 9/84 reads (11%) | catalogued as rs782628376; called by muse, mutect2, varscan2
- PPP3CA | c.648C>T p.D216= | Silent (SNP) | VAF 8/53 reads (15%) | catalogued as COSV59926399; called by muse, varscan2
- RHOBTB1 | c.693A>C p.A231= | Silent (SNP) | VAF 57/421 reads (14%) | called by muse, mutect2, varscan2
- RSF1 | c.2775G>A p.L925= | Silent (SNP) | VAF 40/756 reads (5%) | catalogued as COSV57839086; called by muse, mutect2
- SAMD11 | c.1245C>A p.P415= | Silent (SNP) | VAF 14/108 reads (13%) | called by muse, mutect2, varscan2
- SEPTIN14 | c.951C>G p.G317= | Silent (SNP) | VAF 28/214 reads (13%) | called by muse, varscan2
- SHANK1 | c.2937C>A p.R979= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as rs774323961; called by muse, mutect2, varscan2
- SRGAP2 | c.2010C>T p.I670= (on ENST00000624873 / NM_001170637.4; = p.I671= on NM_015326.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 78/793 reads (10%) | catalogued as COSV55336758; called by muse, mutect2, varscan2
- SSH1 | c.2802G>C p.R934= | Silent (SNP) | VAF 12/63 reads (19%) | called by muse, mutect2, varscan2
- SYT5 | c.45G>T p.T15= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as COSV99670814; called by muse, mutect2, varscan2
- TIGAR | c.165C>T p.F55= | Silent (SNP) | VAF 37/207 reads (18%) | called by muse, mutect2, varscan2
- TMEM191C | c.258C>G p.L86= | Silent (SNP) | VAF 28/269 reads (10%) | called by muse, mutect2, varscan2
- TPM2 | c.621G>T p.L207= | Silent (SNP) | VAF 143/614 reads (23%) | called by muse, mutect2, varscan2
- TRANK1 | c.4986G>A p.E1662= | Silent (SNP) | VAF 53/324 reads (16%) | called by muse, mutect2, varscan2
- TRO | c.804A>T p.I268= | Silent (SNP) | VAF 71/655 reads (11%) | called by muse, mutect2, varscan2
- TTN | c.87733C>T p.L29245= (on ENST00000591111; = p.L21821= on NM_003319.4) | Silent (SNP) | VAF 53/459 reads (12%) | called by muse, mutect2, varscan2
- USP31 | c.2688G>A p.L896= | Silent (SNP) | VAF 19/116 reads (16%) | catalogued as rs999164777; called by muse, mutect2, varscan2
- WDR45 | c.684G>T p.L228= (on ENST00000376372 / NM_001029896.2; = p.L229= on NM_007075.3) | Silent (SNP) | VAF 49/473 reads (10%) | called by muse, mutect2, varscan2
- ZIM3 | c.1254C>A p.T418= | Silent (SNP) | VAF 198/650 reads (30%) | called by muse, mutect2, varscan2
- ZNF135 | c.1551T>C p.T517= (on ENST00000313434 / NM_001289401.2; = p.T529= on NM_003436.4) | Silent (SNP) | VAF 46/632 reads (7%) | called by muse, mutect2
- ZNF292 | c.3075G>A p.V1025= | Silent (SNP) | VAF 40/358 reads (11%) | called by muse, mutect2, varscan2
- ZNF419 | c.567C>T p.S189= | Silent (SNP) | VAF 155/650 reads (24%) | catalogued as rs370782743; called by muse, mutect2, varscan2
- ZNF729 | c.1293C>A p.P431= | Silent (SNP) | VAF 68/485 reads (14%) | catalogued as rs1398902795; called by muse, mutect2, varscan2
- AC112198.2 | n.244C>T | RNA (SNP) | VAF 56/582 reads (10%) | called by muse, mutect2
- AP000769.3 | chr11:65503470 del AA | 5'Flank (DEL) | VAF 30/285 reads (11%) | called by mutect2, pindel
- APLN | c.*33C>A | 3'UTR (SNP) | VAF 43/333 reads (13%) | called by muse, mutect2, varscan2
- ASAH1 | c.506-25G>T | Intron (SNP) | VAF 37/370 reads (10%) | called by muse, mutect2, varscan2
- BMERB1 | chr16:15591098 G>A | 3'Flank (SNP) | VAF 66/579 reads (11%) | catalogued as rs764609043; called by muse, mutect2, varscan2
- BUB1B | c.967-46G>A | Intron (SNP) | VAF 82/475 reads (17%) | called by muse, mutect2, varscan2
- CACNA2D3 | c.3103-10C>A | Intron (SNP) | VAF 44/245 reads (18%) | called by muse, varscan2
- CATSPER1 | c.2201+31G>T | Intron (SNP) | VAF 41/352 reads (12%) | called by muse, varscan2
- CATSPER1 | c.2201+30G>T | Intron (SNP) | VAF 40/362 reads (11%) | called by muse, varscan2
- CDIPT | chr16:29864746 G>A | 5'Flank (SNP) | VAF 30/255 reads (12%) | called by muse, mutect2, varscan2
- CDK1 | c.*35C>T | 3'UTR (SNP) | VAF 12/111 reads (11%) | catalogued as rs1358047044; called by muse, mutect2, varscan2
- COMMD2 | c.228+74C>G | Intron (SNP) | VAF 24/152 reads (16%) | called by muse, mutect2
- CUL4B | c.*4G>T | 3'UTR (SNP) | VAF 72/701 reads (10%) | catalogued as COSV100341298; called by muse, mutect2, varscan2
- ETFB | c.58-136G>T | Intron (SNP) | VAF 161/569 reads (28%) | catalogued as COSV58537274; called by muse, mutect2, varscan2
- FAM167A | c.381+5852G>C | Intron (SNP) | VAF 28/130 reads (22%) | called by muse, mutect2, varscan2
- FCN2 | c.*9G>T | 3'UTR (SNP) | VAF 201/691 reads (29%) | called by muse, mutect2, varscan2
- FOXH1 | c.*10G>C | 3'UTR (SNP) | VAF 4/21 reads (19%) | called by muse, mutect2, varscan2
- KY | c.1090+167G>A | Intron (SNP) | VAF 38/392 reads (10%) | catalogued as rs916730392, COSV71016429, COSV71017933; called by muse, mutect2, varscan2
- LRIG3 | c.1801+88C>G | Intron (SNP) | VAF 18/93 reads (19%) | called by muse, mutect2, varscan2
- NAA60 | c.*206+87G>C | Intron (SNP) | VAF 34/255 reads (13%) | called by muse, mutect2, varscan2
- NAGPA | c.791+49G>A | Intron (SNP) | VAF 32/308 reads (10%) | catalogued as rs1446018979; called by muse, mutect2, varscan2
- PDE4A | chr19:10416892 G>T | 5'Flank (SNP) | VAF 56/332 reads (17%) | called by muse, mutect2, varscan2
- PIGS | c.1081-185G>A | Intron (SNP) | VAF 22/262 reads (8%) | catalogued as COSV52026127; called by muse, mutect2
- PORCN | c.-37-120C>A | Intron (SNP) | VAF 63/548 reads (11%) | called by muse, mutect2, varscan2
- PRECSIT | n.760C>G | RNA (SNP) | VAF 107/918 reads (12%) | called by muse, mutect2, varscan2
- RAB40C | chr16:629984 G>A | 3'Flank (SNP) | VAF 51/366 reads (14%) | called by muse, mutect2, varscan2
- RNU6-1178P | chr17:20895930 T>C | 5'Flank (SNP) | VAF 40/295 reads (14%) | called by muse, mutect2, varscan2
- SEMA4A | c.*17G>T | 3'UTR (SNP) | VAF 83/653 reads (13%) | called by muse, mutect2, varscan2
- SH3RF3 | c.-296C>T | 5'UTR (SNP) | VAF 40/203 reads (20%) | called by muse, mutect2, varscan2
- SIRPB1 | c.76+15871C>A | Intron (SNP) | VAF 83/352 reads (24%) | catalogued as COSV99039392; called by muse, mutect2, varscan2
- TMEM155 | chr4:121766089 G>A | 5'Flank (SNP) | VAF 20/220 reads (9%) | called by muse, mutect2
- TMEM75 | n.1070C>A | RNA (SNP) | VAF 13/125 reads (10%) | called by muse, mutect2, varscan2
- TRIM74 | c.*15G>C | 3'UTR (SNP) | VAF 8/41 reads (20%) | called by mutect2, varscan2
- XIRP2 | c.*465C>A | 3'UTR (SNP) | VAF 41/306 reads (13%) | catalogued as COSV54681869, COSV54691882; called by muse, mutect2, varscan2
